CCDI case PBCLBI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/286ee6eb-f503-4e3e-a3e7-11983319fb7f

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Optic nerve; Age at diagnosis: 14.7 years (5,368 days).

Biospecimens (3 samples)
- Sample 0DUNO8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUNOZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUNP6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
